Gene-level copy-number profile of tumor specimen C3N-02784-01 (profiled together with C3N-02784-03) from CPTAC case C3N-02784, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.1 years (13,569 days).
Specimen C3N-02784-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 707e55ee-3f51-42de-93ff-93eb3154b40f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02784-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/3afe4434-efca-4ecf-9d27-38682849f0ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 102; copy number 2: 54,441; copy number 3: 21; copy number 4: 3,786; copy number 5: 12; copy number 6: 2; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,687,814–109,709,039, 2 genes (within-gene range 0–2): GSTM1, AC000032.1.
- chr1:120,489,860–120,850,985, 7 genes (within-gene range 0–2): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19.
- chr1:248,548,756–248,565,299, 3 genes (within-gene range 0–7): AC098483.1, OR2AS1P, OR2T29.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr15:34,415,450–34,588,503, 7 genes (within-gene range 0–2): AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 5: CFHR3.
- chr5:71,032,670–71,093,193, 2 genes, copy number 5: GTF2H2, OCLNP1.
- chr8:12,115,767–12,177,550, 5 genes, copy number 5 (within-gene range 2–5): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D.
- chr14:18,692,032–18,712,643, 4 genes, copy number 5: RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr15:32,436,503–32,455,634, 3 genes, copy number 8: DNM1P32, GOLGA8O, RN7SL539P.
- chr15:32,536,047–32,587,613, 2 genes, copy number 6 (within-gene range 2–6): LINC02256, AC123768.3.

Autosomal genes at a single copy (total copy number 1): 95. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
